Somatic mutation profile of tumor specimen 0DIMX3 from CCDI case PBBVRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Cerebrum; Age at diagnosis: 2.5 years (930 days).
Specimen 0DIMX3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ac6855-a9f8-4999-9fdf-bbda1551c182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/595a5c84-f88e-4d8d-9b73-e28b195a2f6c

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAM | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 183/614 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs759931794; called by muse, mutect2, varscan2
- ADAMTS14 | c.3425A>G p.D1142G | Missense Mutation (SNP) | VAF 363/663 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CELSR3 | c.6216C>G p.D2072E | Missense Mutation (SNP) | VAF 332/600 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MRPS26 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- NOM1 | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 312/756 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PRKCB | c.1386C>T p.I462= | Silent (SNP) | VAF 118/524 reads (23%) | catalogued as COSV57776961; called by muse, mutect2, varscan2
- TEKT1 | c.807G>A p.K269= | Silent (SNP) | VAF 288/962 reads (30%) | catalogued as COSV58622090; called by muse, mutect2
